Somatic mutation profile of tumor specimen TARGET-40-0A4I8U-01A (aliquot TARGET-40-0A4I8U-01A-01D) from TARGET case TARGET-40-0A4I8U, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.1 years (7,328 days).
Specimen TARGET-40-0A4I8U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3117d62c-ee1c-4295-b6d5-256654618ccb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I8U-10A (Blood Derived Normal), aliquot TARGET-40-0A4I8U-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0a19275-de58-4ecb-833a-c63046fc4bcc

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Intron 7, Silent 6, Nonsense Mutation 3, Splice Site 3, RNA 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8113G>A p.V2705I | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs587779870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCLK2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 234/348 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1230886415, COSV56203727; called by muse, mutect2, varscan2
- DYSF | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 40/371 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs371609233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDI2 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV66336273; called by muse, mutect2, varscan2
- KRTAP10-9 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 48/1058 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.262); catalogued as rs587699794; called by muse, mutect2
- LY6G6F-LY6G6D | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 38/994 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs749059592, COSV65419295; called by muse, mutect2
- OR12D2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 81/540 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs549345993, COSV101011485; called by muse, mutect2, varscan2
- PTPRH | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as COSV99670746; called by muse, mutect2, varscan2
- RYR3 | c.5938C>T p.R1980* | Nonsense Mutation (SNP) | VAF 117/382 reads (31%) | catalogued as COSV66786061, COSV66809822; called by muse, mutect2, varscan2
- WDHD1 | c.1828A>G p.K610E | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1182165823; called by muse, mutect2, varscan2
- ADH1A | c.125T>A p.V42E | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- AKAP13 | c.2536G>T p.G846C | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- AKAP13 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ARHGEF15 | c.2270-1G>C p.X757_splice | Splice Site (SNP) | VAF 250/1370 reads (18%) | called by muse, varscan2
- ARHGEF16 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ATP6V1B1 | c.274-1G>A p.X92_splice | Splice Site (SNP) | VAF 43/379 reads (11%) | called by muse, mutect2, varscan2
- CRYZ | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 67/524 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAGLA | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DOCK6 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ECHS1 | c.347T>A p.F116Y | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- EMSY | c.3746A>T p.E1249V | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FER | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- HMGA1 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL21 | c.941G>A p.W314* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- MROH7 | c.3192C>A p.N1064K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MROH7 | c.3193C>A p.L1065I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- MUC5B | c.8817C>A p.D2939E | Missense Mutation (SNP) | VAF 72/416 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RELCH | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SPDYE5 | c.*46-2A>G | Splice Site (SNP) | VAF 242/782 reads (31%) | called by muse, mutect2, varscan2
- VNN1 | c.532A>C p.K178Q | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDPCP | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ZNF547 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF15 | c.1941G>A p.R647= | Silent (SNP) | VAF 196/1338 reads (15%) | called by muse, mutect2, varscan2
- CLTCL1 | c.4710C>G p.L1570= (on ENST00000427926 / NM_007098.4; = p.L1513= on NM_001835.4) | Silent (SNP) | VAF 171/487 reads (35%) | catalogued as rs782088255; called by muse, mutect2, varscan2
- LARP1 | c.669C>A p.T223= (on ENST00000518297 / NM_033551.3; = p.T146= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 16/468 reads (3%) | called by muse, mutect2
- MYH3 | c.4464C>T p.A1488= | Silent (SNP) | VAF 70/1262 reads (6%) | called by muse, mutect2
- RPS29 | c.34C>A p.R12= | Silent (SNP) | VAF 55/347 reads (16%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.2877A>T p.I959= | Silent (SNP) | VAF 53/186 reads (28%) | called by muse, mutect2, varscan2
- ACE | c.2642-78G>A | Intron (SNP) | VAF 43/269 reads (16%) | catalogued as rs780128133, COSV52011878; called by muse, mutect2, varscan2
- ACSM5P1 | n.874A>G | RNA (SNP) | VAF 49/238 reads (21%) | called by muse, mutect2, varscan2
- CLTCL1 | c.4606-70C>T | Intron (SNP) | VAF 67/199 reads (34%) | catalogued as rs180955104; called by muse, mutect2, varscan2
- ERLIN2 | chr8:37736027 C>T | 5'Flank (SNP) | VAF 18/32 reads (56%) | catalogued as rs1398761246; called by muse, varscan2
- HHLA1 | c.140-1093G>A | Intron (SNP) | VAF 95/234 reads (41%) | catalogued as rs570057578; called by muse, mutect2, varscan2
- JPH2 | c.379+8460C>T | Intron (SNP) | VAF 35/152 reads (23%) | catalogued as rs1462082788; called by muse, mutect2, varscan2
- KRTAP20-3 | c.-23C>A | 5'UTR (SNP) | VAF 158/299 reads (53%) | called by muse, mutect2, varscan2
- LEMD2 | c.1011-30A>G | Intron (SNP) | VAF 87/230 reads (38%) | catalogued as rs762539768; called by muse, mutect2, varscan2
- LINC00315 | n.1184G>T | RNA (SNP) | VAF 29/280 reads (10%) | called by muse, mutect2, varscan2
- MMP16 | c.404+72T>C | Intron (SNP) | VAF 49/455 reads (11%) | called by muse, mutect2, varscan2
- NDUFA10 | c.1000-12471G>T | Intron (SNP) | VAF 91/158 reads (58%) | called by muse, mutect2, varscan2
